Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A6B7, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A6B7-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

* Addendum *

Patient: [REDACTED]

CC: [REDACTED]

ICD-0-3
leiomyosarcoma 8890/3
Site: Retroperitoneum C48.0
JW 5/21/13

....

Clinical Diagnosis & History:
Retroperitoneal sarcoma.

Specimens Submitted:

1: Radical resection left retroperitoneal mass and left nephrectomy

DIAGNOSIS:

1. Left retroperitoneal "mass" resection and left nephrectomy:
- High grade leiomyosarcoma, involving renal vein and adjacent soft tissue.
- Tumor size: 11.5 x 9 x 8.5 cm.
- Tumor shows areas of necrosis and hyalinization, comprising approximately 20% of the mass.
- Tumor is present at the renal vein margin, present as an intra-luminal tumor embolus.
- Within the soft tissue, the tumor is covered by thin fibrous tissue grossly, which represents the surgical margin.
- Renal parenchyma shows a small fibrotic nodule (0.4 cm in the lower pole) with a bland spindle cell proliferation; further immuno-work-up will be performed for a more definitive classification. The remaining renal parenchyma is unremarkable.
- Renal artery is not involved by tumor.
- One benign lymph node (0/1).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	RECUT	
	RECUT	

Gross Description:

** Continued on next page **

[page 2 of 3]
1. The specimen is received fresh, labeled "radical resection left retroperitoneal mass and left nephrectomy", and consists of a retroperitoneal mass with attached kidney, ureter, renal vessels, and perinephric fat weighing 1510 g in total and measures 21 x 17 x 14 cm. The retroperitoneal mass measures 11.5 x 9 x 8.5 cm. The mass is inferior to kidney, partially bulging to the inferior aspect of the renal pelvis, abutting to inferior aspect of renal parenchyma. The mass is covered by intact white fibrous membrane. Cut surface of mass show white, firm, nodular and whorling surface. There is focus of myxoid and yellow necrotic area measuring 2 cm in greatest dimension, representing approximately 2% of tumor volume. The mass is associated with the entire segment of renal vein submitted and extends to the resection margin of the renal vein, which is inked black. The renal vein measures 6 x 1 x 1 cm. The renal artery measures 2 cm in length and is grossly not involved by the mass. The potential ureter is surrounded by the mass. The renal artery and ureter margins are grossly unremarkable. An adrenal gland is not identified. The kidney measures 14.5 x 9 x 7.5 cm. The kidney is bivalved to reveal one tan firm nodule measuring 0.4 cm in diameter in the inferior pole, 1 cm from the retroperitoneal mass. The renal pelvis is slightly dilated. Sections through the remainder of the kidney reveal pink brown parenchyma, with a well-defined cortico-medullary junction. The cortex measures 0.7 cm and the calyces appear normal. No lymph nodes are identified in the perinephric fat. The specimen is photographed. Representative sections are submitted for TPS and for permanent sections.

Summary of sections:

UVM -- ureteral and renal artery margins, enface
RV--renal vein margin, perpendicular section
TV--tumor with renal vein
TA--renal artery
THF-- tumor with hilar fat
TK -- tumor with adjacent kidney
T tumor
N--nodule in lower pole
RP -- renal pelvis, representative sections
K -- non-neoplastic kidney, representative sections

Summary of Sections:

Part 1: Radical resection left retroperitoneal mass and left nephrectomy

Block	Sect.	Site	PCs
1		K	1
1		N	1
1		RP	1
1		RV	2
9		T	9
2		TA	2
2		THF	2

** Continued on next page **

[page 3 of 3]
[REDACTED]

[REDACTED]

----- Page 3 of 3

2	TK	2
2	TV	2
1	UVM	3

Procedures/Addenda:
Addendum
Date Ordered: Status: Signed Out
Date Complete:
Date Reported:

Addendum Diagnosis
The additional stains performed show only focal reactivity for SMA while desmin is negative. These results are not supportive of a metastatic nodule to the kidney.

*** Report Electronically Signed Out ***
Signed out by

** End of Report **

Criteria	W 5/5/13	Yes	No
HIVAA Discrepancy			✓

Source: NCI Genomic Data Commons file 5b6a43b7-97ba-4f50-9f49-7ac3292401cf (TCGA-DX-A6B7.539326A4-0C01-466F-BB32-CB0054D01FBD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).